Gene-level copy-number profile of tumor specimen TCGA-BT-A2LD-01A from TCGA case TCGA-BT-A2LD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.5 years (28,673 days).
Specimen TCGA-BT-A2LD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a382992a-0bb7-401a-af1e-bd0bef7b557a.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,474 have no estimate.
https://portal.gdc.cancer.gov/files/a0986e12-df47-49d7-aaf8-6b24bb76b80b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,845; copy number 2: 36,592; copy number 3: 13,936; copy number 4: 398; copy number 5: 492; copy number 6: 486; copy number 7: 400.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A2LD-01A-12D-A20B-01): tumor purity 0.59, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,378 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:41,143,780–48,780,895, 150 genes, copy number 5 (broad region; genes not listed).
- chr2:54,972,187–57,544,599, 37 genes, copy number 6: RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63, EIF2S2P7, AC132153.1, AC068276.1, AC073875.1.
- chr2:58,427,799–59,063,766, 1 gene, copy number 5 (within-gene range 4–5): LINC01122.
- chr2:59,014,354–62,662,829, 76 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:74,881,174–75,050,115, 5 genes, copy number 7: AC098825.1, HSPE1P23, PARM1, PARM1-AS1, AC110760.1.
- chr4:76,435,229–76,783,253, 1 gene, copy number 7 (within-gene range 4–7): SHROOM3.
- chr4:76,575,551–77,433,388, 16 genes, copy number 7 (within-gene range 4–7): MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr4:85,475,150–89,999,409, 82 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr4:90,370,123–90,683,123, 2 genes, copy number 7: RN7SKP248, AC093729.1.
- chr6:19,612,755–21,602,383, 28 genes, copy number 7: KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 7: AL136313.1.
- chr8:88,032,011–91,398,155, 36 genes, copy number 5 (within-gene range 3–5): MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:95,133,785–95,811,254, 6 genes, copy number 7 (within-gene range 4–7): PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1.
- chr8:96,370,800–102,412,759, 126 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr10:3,232,264–3,556,314, 7 genes, copy number 5 (within-gene range 3–5): LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1.
- chr10:4,024,903–9,309,772, 107 genes, copy number 5 (broad region; genes not listed).
- chr13:72,453,902–74,565,445, 33 genes, copy number 5: AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347.
- chr19:28,790,812–32,244,083, 45 genes, copy number 7: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472.
- chr19:36,383,120–36,489,902, 3 genes, copy number 6: ZFP82, AC092296.3, ZNF566.
- chr19:37,884,823–40,576,464, 141 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr19:53,281,559–57,953,759, 371 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr20:49,237,946–54,651,169, 104 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
